Somatic mutation profile of tumor specimen HCM-WCMC-0946-C34-01A (aliquot HCM-WCMC-0946-C34-01A-15D-A905-36) from HCMI case HCM-WCMC-0946-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 79.9 years (29,167 days).
Specimen HCM-WCMC-0946-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 596a4b66-cec9-4d05-a65e-b1202b1ec162.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0946-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0946-C34-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea13c4f7-d98c-40ee-9214-cbf58312c079

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENTPD7 | c.586T>A p.L196I | Missense Mutation (SNP) | VAF 20/580 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs1164546473; called by muse, mutect2
- FBN1 | c.1905C>G p.Y635* | Nonsense Mutation (SNP) | VAF 20/560 reads (4%) | catalogued as CM095635; called by muse, mutect2
- PROS1 | c.1429G>T p.V477F | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV67775412; called by muse, mutect2
- OR4C15 | c.979T>C p.F327L (on ENST00000314644; = p.F273L on NM_001001920.2) | Missense Mutation (SNP) | VAF 17/648 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.044); called by muse, mutect2
